Gene-level copy-number profile of tumor specimen ALCH-B3CJ-TTP1-A from ALCHEMIST case ALCH-B3CJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,123 days).
Specimen ALCH-B3CJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f33bd30a-fd73-409d-8af5-9a1bb92f5082.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3CJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/3f05ed0e-a42a-4d1a-8074-499e973c0d22

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 29,638; copy number 2: 26,295; copy number 3: 2,083; copy number 4: 233; copy number 5: 9.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:266,855–268,655, 1 gene: AP006222.2.
- chr1:722,092–817,712, 7 genes (within-gene range 0–1): CICP3, AL669831.1, RNU6-1199P, AL669831.2, LINC01409, AL669831.6, AL669831.4.
- chr1:4,654,609–7,985,505, 57 genes: AJAP1, Z98886.1, LINC02782, Z98259.3, Z98259.1, AL365255.1, Z97988.1, MIR4689, NPHP4, KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672, CAMTA1-DT, CAMTA1, AL590128.1, AL512330.1, RNU1-8P, CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1, AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA.
- chr4:119,317,250–119,454,638, 7 genes: FABP2, KLHL2P1, RNU4-33P, AC110373.1, GTF2IP12, AC093752.3, RNU6-1217P.
- chr4:119,456,350–119,457,277, 1 gene (within-gene range 0–1): AC093752.2.
- chr5:67,001,383–67,003,953, 1 gene (within-gene range 0–1): MAST4-AS1.
- chr6:32,549,940–32,560,022, 2 genes (within-gene range 0–2): RNU1-61P, HLA-DRB6.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–1): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:61,330,717–61,453,030, 2 genes: CNTNAP3C, RN7SL462P.
- chr9:61,615,835–61,627,683, 1 gene: FAM242D.
- chr11:3,189,546–3,189,929, 1 gene: AC108448.1.
- chr14:100,725,705–100,738,224, 1 gene: DLK1.
- chr16:28,494,643–28,512,051, 2 genes (within-gene range 0–1): APOBR, IL27.
- chr19:301,444–344,815, 2 genes (within-gene range 0–1): MIER2, AC016588.1.
- chr20:12,865,202–16,053,197, 34 genes: LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1, AL079338.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 2,325 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 3: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr2:8,721,081–32,946,149, 435 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr2:43,230,836–43,596,046, 3 genes, copy number 3 (within-gene range 2–3): THADA, RNU6-958P, RN7SL531P.
- chr2:113,888,203–125,823,315, 109 genes, copy number 3 (broad region; genes not listed).
- chr2:128,350,829–128,581,576, 4 genes, copy number 3: Y_RNA, RNA5SP103, ISCA1P6, AC012451.1.
- chr2:129,825,126–133,568,463, 156 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:168,834,132–177,223,958, 167 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr2:177,603,089–180,939,298, 49 genes, copy number 3: AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2, FKBP7, PLEKHA3, TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1, AC092640.1, CCDC141, RNU7-104P, RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3.
- chr2:186,486,253–203,075,142, 271 genes, copy number 3 (broad region; genes not listed).
- chr3:151,637,174–183,116,075, 441 genes, copy number 3 (broad region; genes not listed).
- chr3:187,368,385–198,123,232, 229 genes, copy number 4 (broad region; genes not listed).
- chr5:39,105,252–39,274,528, 1 gene, copy number 3 (within-gene range 2–3): FYB1.
- chr7:71,779,491–72,447,151, 1 gene, copy number 3 (within-gene range 2–3): CALN1.
- chr7:72,103,181–79,453,667, 190 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr8:105,826,570–106,272,902, 5 genes, copy number 3 (within-gene range 2–3): AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr9:60,914,407–61,212,373, 9 genes, copy number 5: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4.
- chr10:59,551,404–63,521,850, 43 genes, copy number 3 (within-gene range 2–3): MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2, LINC02621, AC024597.1, RN7SL591P, ZNF365, AC024598.1, AC067752.1, AC067751.1, ALDH7A1P4, ADO, EGR2, RNU6-543P, AL590502.1, NRBF2, JMJD1C, TATDN1P1, AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1.
- chr11:11,656,651–11,656,722, 1 gene, copy number 3: MIR4299.
- chr12:130,024,493–133,238,549, 138 genes, copy number 3 (broad region; genes not listed).
- chr19:1,107,637–1,174,268, 1 gene, copy number 3: SBNO2.
- chr20:49,632,945–52,670,578, 63 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr20:55,074,644–55,075,140, 1 gene, copy number 3: RPL12P4.
- chr22:45,657,019–45,680,130, 1 gene, copy number 3 (within-gene range 2–3): Z95331.1.

Autosomal genes at a single copy (total copy number 1): 27,294. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
